CCDI case PBBXGB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/400a6839-a86a-43b3-b865-67c018799601

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Pineoblastoma: ICD-O-3 morphology code: 9362/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.3 years (2,659 days).

Biospecimens (3 samples)
- Sample 0DJO4T: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DJO58: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DJO5G: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
